Somatic mutation profile of tumor specimen 0DOQG7 from CCDI case PBCAWW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Paraganglioma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 13.5 years (4,943 days).
Specimen 0DOQG7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8011c4c5-d1ec-4999-98ef-7ae6a00e1af5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOQGM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4bdac38-f94d-423e-a516-37269a080943

The open-access MAF lists 21 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Intron 3, 3'UTR 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PEAR1 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 128/668 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs1053986252; called by muse, mutect2, varscan2
- ACBD5 | c.748A>G p.N250D (on ENST00000375888 / NM_001352568.1; = p.N241D on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/943 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- ADAMTS8 | c.1839G>C p.K613N | Missense Mutation (SNP) | VAF 22/687 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ATP8B2 | c.2933T>C p.L978P (on ENST00000672630; = p.L945P on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 197/856 reads (23%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- BATF | c.242A>T p.Y81F | Missense Mutation (SNP) | VAF 20/521 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- BTAF1 | c.962G>A p.G321D | Missense Mutation (SNP) | VAF 359/1275 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CC2D1A | c.2599C>T p.Q867* | Nonsense Mutation (SNP) | VAF 24/489 reads (5%) | called by muse, mutect2
- CLEC4D | c.527A>T p.N176I | Missense Mutation (SNP) | VAF 33/1252 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2
- DNAH6 | c.9070G>A p.D3024N | Missense Mutation (SNP) | VAF 39/807 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- MMP11 | c.108G>A p.P36= | Splice Region (SNP) | VAF 36/388 reads (9%) | called by muse, mutect2
- SLIT1 | c.480A>T p.K160N | Missense Mutation (SNP) | VAF 28/1056 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPTB | c.4309G>A p.E1437K | Missense Mutation (SNP) | VAF 114/779 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- COL2A1 | c.2817C>T p.G939= | Silent (SNP) | VAF 62/999 reads (6%) | catalogued as rs1328170570, COSV100477751; called by muse, mutect2
- FBXL8 | c.138C>T p.H46= | Silent (SNP) | VAF 35/713 reads (5%) | catalogued as rs1238922060; called by muse, mutect2
- PPOX | c.1107G>A p.L369= | Silent (SNP) | VAF 108/1175 reads (9%) | catalogued as rs756580371; called by muse, mutect2
- SLC41A2 | c.366G>A p.E122= | Silent (SNP) | VAF 23/865 reads (3%) | called by muse, mutect2
- STOX1 | c.1149A>G p.K383= | Silent (SNP) | VAF 28/894 reads (3%) | called by muse, mutect2
- CHRD | c.1932+55G>A | Intron (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- HMGB1 | c.*85T>C | 3'UTR (SNP) | VAF 9/218 reads (4%) | catalogued as COSV100360835; called by muse, mutect2
- HSD17B1 | c.98-44G>A | Intron (SNP) | VAF 38/618 reads (6%) | called by muse, mutect2
- MRPS18C | c.151-19T>C | Intron (SNP) | VAF 99/761 reads (13%) | called by muse, mutect2, varscan2
